Somatic mutation profile of tumor specimen TARGET-10-PAPETC-09A (aliquot TARGET-10-PAPETC-09A-01D) from TARGET case TARGET-10-PAPETC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,727 days).
Specimen TARGET-10-PAPETC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273bb8ff-382c-4734-aef3-76746d47cc89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPETC-14A (Bone Marrow Normal), aliquot TARGET-10-PAPETC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1e72cc8-2031-4c17-92b5-8bde68cea50f

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 5'Flank 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIP4K2C | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | catalogued as rs1459350575; called by muse, varscan2
- TLE3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1468087824, COSV58167025, COSV58174440; called by muse, mutect2, varscan2
- AMPD2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ANXA10 | c.471C>A p.N157K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, mutect2
- CNP | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- CYP2C9 | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- IGLV10-54 | chr22:22215269 TCAC>CCT | Missense Mutation (DEL) | VAF 12/24 reads (50%) | called by pindel, varscan2*
- MUC17 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME1-NME2 | c.716C>T p.S239L (on ENST00000555572; = p.S214L on NM_001018136.3) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SLC27A2 | c.600A>C p.E200D | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TECRL | c.733T>A p.F245I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- TRIM75P | c.80T>A p.V27D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AGPAT1 | c.237G>A p.L79= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100421702; called by muse, mutect2, varscan2
- DMD | c.4656T>C p.Y1552= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- OR5M10 | c.87G>T p.G29= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs752259142; called by muse, mutect2, varscan2
- ADAT1 | chr16:75597299 C>T | 3'Flank (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- CELA3A | chr1:21998211 G>A | 5'Flank (SNP) | VAF 23/103 reads (22%) | catalogued as rs898044811; called by muse, mutect2, varscan2
